Somatic mutation profile of tumor specimen TCGA-29-1701-01A (aliquot TCGA-29-1701-01A-01W-0633-09) from TCGA case TCGA-29-1701, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.8 years (20,737 days).
Specimen TCGA-29-1701-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfbde31a-a091-44a2-b6d2-28b08f9bc16e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1701-10A (Blood Derived Normal), aliquot TCGA-29-1701-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27bc4c3a-ce8f-409a-8ca5-696e9fdfe406

The open-access MAF lists 79 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 16, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 2, RNA 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.994-2A>G p.X332_splice | Splice Site (SNP) | VAF 71/108 reads (66%) | hotspot (GDC flag); catalogued as rs867389695, CS159286, COSV52692098, COSV52692518, COSV53122371; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.1818dup p.Q607Afs*6 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | catalogued as rs747169251; called by mutect2, pindel
- ADGRB2 | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.263); catalogued as rs774040499, COSV57073908; called by muse, mutect2, varscan2
- ALMS1 | c.10057C>A p.P3353T | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV100043861; called by muse, mutect2
- ARHGEF10 | c.3199G>A p.V1067I (on ENST00000398564; = p.V1042I on NM_014629.4) | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs758678206, COSV50651494; called by mutect2, varscan2
- ARPP21 | c.1952C>T p.T651M | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs139862817; called by muse, mutect2, varscan2
- BTBD9 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs150015110, COSV58426603; called by muse, mutect2, varscan2
- CCDC144A | c.3628A>T p.I1210L | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100138721; called by muse, mutect2
- CCDC9B | c.609dup p.T204Hfs*56 | Frame Shift Ins (INS) | VAF 11/85 reads (13%) | catalogued as rs772754432; called by mutect2, varscan2
- CDH8 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs372550272; called by muse, mutect2
- CHRNB2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.85); catalogued as rs199919525, COSV63808329; called by muse, mutect2, varscan2
- CNTN1 | c.2263A>G p.K755E | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.309); catalogued as COSV61639971; called by muse, mutect2, varscan2
- CRMP1 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV100272401; called by muse, mutect2
- CSMD3 | c.1928C>G p.T643R (on ENST00000297405 / NM_001363185.1; = p.T539R on NM_052900.3) | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52120043, COSV52190191; called by muse, mutect2, varscan2
- CYLC2 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as rs780357420, COSV66337727, COSV66339704; called by muse, mutect2, varscan2
- FER | c.1763T>C p.V588A | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99814074; called by muse, mutect2
- FRMD7 | c.1492T>C p.Y498H | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs910445814, CD087853, CD118788; called by muse, mutect2
- GAD2 | c.988T>G p.F330V | Missense Mutation (SNP) | VAF 56/490 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV52158099; called by muse, mutect2, varscan2
- GANAB | c.692A>G p.K231R | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV60464994; called by muse, mutect2, varscan2
- HMGCR | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV55315830; called by muse, varscan2
- IGHV1-45 | c.307A>G p.S103G | Missense Mutation (SNP) | VAF 23/403 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs782689501; called by muse, mutect2
- IGKV2D-28 | c.340A>C p.M114L | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV101494568; called by mutect2, varscan2
- KIF21A | c.3956G>T p.R1319I (on ENST00000361418 / NM_001378440.1; = p.R1306I on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100735693; called by muse, mutect2
- LRPPRC | c.4115T>G p.F1372C | Missense Mutation (SNP) | VAF 93/246 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53238728; called by muse, mutect2, varscan2
- LRRTM4 | c.694C>A p.R232S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV69138827, COSV69140361; called by muse, mutect2, varscan2
- LY6G5B | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as rs1018318235, COSV65498130; called by muse, mutect2
- MAGEA11 | c.416A>C p.Q139P | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100290723; called by muse, mutect2, varscan2
- MLLT10 | c.2734A>G p.I912V (on ENST00000307729 / NM_001195626.3; = p.I928V on NM_004641.3) | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV56991595, COSV56996371; called by muse, mutect2, varscan2
- OR4A16 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.023); catalogued as COSV100125057; called by muse, mutect2
- OR8G5 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 30/462 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV58380101, COSV58383992; called by muse, mutect2
- OSBP | c.2188G>C p.D730H | Missense Mutation (SNP) | VAF 38/486 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99803429; called by muse, mutect2
- PCDHA13 | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.354); catalogued as COSV56505309; called by muse, mutect2, varscan2
- PI15 | c.89C>A p.S30* | Nonsense Mutation (SNP) | VAF 108/289 reads (37%) | catalogued as rs1412304855, COSV52641732; called by muse, mutect2, varscan2
- PPP1R16B | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs376987738; called by muse, mutect2
- PRDM4 | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV57307859, COSV99946756; called by muse, mutect2
- PRKG1 | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64770998; called by muse, mutect2, varscan2
- RGS22 | c.725-1G>C p.X242_splice | Splice Site (SNP) | VAF 60/1166 reads (5%) | catalogued as COSV100693856; called by muse, mutect2
- RHEX | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs531574406, COSV58980514; called by muse, mutect2, varscan2
- SALL4 | c.635C>A p.P212Q | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV53852511; called by muse, mutect2, varscan2
- SEMA5B | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99533312; called by muse, mutect2
- SH3PXD2A | c.1918G>A p.G640R (on ENST00000369774 / NM_001365079.1; = p.G612R on NM_014631.2) | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.007); catalogued as rs376504935; called by muse, mutect2
- SLFN11 | c.2490G>C p.M830I | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100391053; called by muse, mutect2
- SOX6 | c.1336A>G p.N446D (on ENST00000528429 / NM_001145819.2; = p.N405D on NM_017508.3) | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV100323339; called by muse, mutect2
- SPAG1 | c.182G>C p.C61S | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99309515; called by muse, mutect2
- TCF20 | c.5633C>T p.A1878V | Missense Mutation (SNP) | VAF 18/530 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100166967; called by muse, mutect2
- TECTA | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 17/533 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99881658; called by muse, mutect2
- TLL1 | c.653G>C p.R218P | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV50274256, COSV50284655; called by muse, mutect2, varscan2
- TPCN1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59235563; called by muse, mutect2, varscan2
- TRAV19 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs774931881; called by muse, mutect2, varscan2
- TSPAN14 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99627942; called by muse, mutect2
- WDFY3 | c.1501A>G p.R501G | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV55701934; called by muse, mutect2, varscan2
- ZNF283 | c.1123T>A p.Y375N | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100191097; called by muse, mutect2
- ZNF426 | c.712T>G p.Y238D | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99465449; called by muse, mutect2
- ZNF804B | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100306405; called by muse, mutect2
- CASR | c.353del p.N118Tfs*6 | Frame Shift Del (DEL) | VAF 163/321 reads (51%) | called by mutect2, pindel, varscan2
- GPI | c.993del p.F331Lfs*71 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, varscan2
- GPI | c.992T>A p.F331Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); called by mutect2, varscan2
- HFM1 | c.1182G>T p.R394S | Missense Mutation (SNP) | VAF 6/158 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCLO | c.2412G>T p.Q804H | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.871); called by muse, mutect2
- TMEM106A | c.729_744del p.Y244Efs*9 | Frame Shift Del (DEL) | VAF 112/770 reads (15%) | called by mutect2, pindel, varscan2
- AHDC1 | c.492G>A p.Q164= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99899770; called by muse, mutect2
- BMP7 | c.1152C>T p.H384= | Silent (SNP) | VAF 34/195 reads (17%) | catalogued as COSV67780899; called by muse, mutect2, varscan2
- CDH10 | c.744C>G p.G248= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV100051466, COSV100053232; called by muse, mutect2
- CLCNKB | c.1332C>T p.L444= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1309674661, CD117817, COSV65160628; called by muse, mutect2, varscan2
- COPZ1 | c.162G>C p.R54= | Silent (SNP) | VAF 44/1607 reads (3%) | catalogued as COSV100017716; called by muse, mutect2
- FCRL1 | c.1146A>G p.S382= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV100839912; called by muse, mutect2
- HCN3 | c.939C>T p.G313= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs747740586, COSV64233373, COSV64234230; called by muse, mutect2, varscan2
- KIAA1958 | c.1584C>T p.R528= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV61723980; called by muse, varscan2
- KRT31 | c.165C>T p.S55= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV52435402; called by muse, mutect2, varscan2
- LY6G6F | c.888C>T p.P296= | Silent (SNP) | VAF 65/324 reads (20%) | catalogued as COSV65434529; called by muse, mutect2, varscan2
- NSMAF | c.2586C>A p.G862= | Silent (SNP) | VAF 11/382 reads (3%) | catalogued as COSV99233505; called by muse, mutect2
- SMARCC2 | c.915T>G p.P305= | Silent (SNP) | VAF 16/231 reads (7%) | catalogued as COSV99911980; called by muse, mutect2
- TPI1 | c.669C>T p.H223= (on ENST00000229270; = p.H186= on NM_000365.6) | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs369241009, COSV51290186; called by muse, mutect2
- WASF2 | c.15G>A p.T5= | Silent (SNP) | VAF 41/347 reads (12%) | catalogued as rs764392418, COSV71004895, COSV71005624; called by muse, mutect2, varscan2
- ZNF217 | c.1350C>T p.P450= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs1166545689, COSV56597454; called by muse, mutect2, varscan2
- ZSCAN5B | c.1359C>T p.N453= | Silent (SNP) | VAF 72/244 reads (30%) | catalogued as rs1399318748, COSV62000249; called by muse, mutect2, varscan2
- DST | c.4297-1720G>C | Intron (SNP) | VAF 18/154 reads (12%) | catalogued as rs748272410, COSV55016589; called by muse, mutect2, varscan2
- LINC02877 | n.330C>A | RNA (SNP) | VAF 94/811 reads (12%) | called by muse, mutect2, varscan2
- ZNF665 | c.-31C>A | 5'UTR (SNP) | VAF 33/482 reads (7%) | catalogued as COSV101128852; called by muse, mutect2
